Somatic mutation profile of tumor specimen 0DMKL3 from CCDI case PBCASM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.8 years (5,401 days).
Specimen 0DMKL3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e71d7291-48ad-4eb7-a852-3bba4ed11237.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2735b7c-b9fa-4bbd-9f70-e98822ed9106

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK9 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 125/1157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775293436; called by muse, mutect2, varscan2
- OR8B4 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 144/502 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs371189371, COSV62069699; called by muse, mutect2, varscan2
- PPP1R7 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 58/1668 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52145698; called by muse, mutect2
- ANPEP | c.799_800del p.T267* | Frame Shift Del (DEL) | VAF 694/1214 reads (57%) | called by mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 60/1537 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- MRPS35 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 128/700 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MRPS35 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 126/701 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SEZ6 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 74/1010 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ZNF148 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 317/718 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- KIF1A | c.15G>T p.S5= | Silent (SNP) | VAF 90/1393 reads (6%) | called by muse, mutect2
- PTPRT | c.1116G>A p.P372= | Silent (SNP) | VAF 379/1326 reads (29%) | catalogued as rs201463497, COSV61967512; called by muse, mutect2, varscan2
